Somatic mutation profile of tumor specimen MP2PRT-PARYCA-TMP1-A (aliquot MP2PRT-PARYCA-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PARYCA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (739 days).
Specimen MP2PRT-PARYCA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 722c4936-11b8-4219-97d1-09927e2732f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARYCA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARYCA-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08062a49-0c42-4cb5-87a9-e5833ad0eb13

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, 3'Flank 1, In Frame Ins 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 42/318 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- EZH2 | c.2215_2216insGCTGGGGCCGCA p.G738_I739insSWGR (on ENST00000460911 / NM_001203247.2; = p.G743_I744insSWGR on NM_004456.5) | In Frame Ins (INS) | VAF 38/260 reads (15%) | catalogued as COSV57462071; called by mutect2, pindel, varscan2
- KCNB2 | c.1967G>T p.R656I | Missense Mutation (SNP) | VAF 58/410 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.828); catalogued as COSV73049391; called by muse, mutect2, varscan2
- MRPS17 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.915); catalogued as COSV53392386; called by muse, mutect2
- RTP5 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 114/640 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.082); catalogued as rs764985888, COSV58319099; called by muse, varscan2
- BLM | c.3607del p.A1203Rfs*2 | Frame Shift Del (DEL) | VAF 45/291 reads (15%) | called by mutect2, pindel, varscan2
- IGHV3-43 | chr14:106470255 TCACTGTGTAT>CCTG | Missense Mutation (DEL) | VAF 35/158 reads (22%) | called by pindel, varscan2*
- KIF25 | c.980G>C p.C327S | Missense Mutation (SNP) | VAF 72/567 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAD21 | c.247_248insCCCT p.I83Tfs*3 | Frame Shift Ins (INS) | VAF 46/222 reads (21%) | called by mutect2, pindel, varscan2
- STC2 | c.282A>T p.K94N | Missense Mutation (SNP) | VAF 58/298 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, varscan2
- BTNL3 | c.1083C>T p.D361= | Silent (SNP) | VAF 44/325 reads (14%) | catalogued as rs754555371, COSV61564562; called by muse, mutect2, varscan2
- COL25A1 | c.1260A>G p.K420= | Silent (SNP) | VAF 50/394 reads (13%) | catalogued as COSV101211121; called by muse, varscan2
- GRIA2 | c.1710C>T p.Y570= | Silent (SNP) | VAF 30/276 reads (11%) | catalogued as rs538981621, COSV52380934, COSV99642409; called by muse, varscan2
- RYR2 | c.9351C>T p.F3117= | Silent (SNP) | VAF 21/180 reads (12%) | catalogued as rs773455753, COSV63693694; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGKV3D-11 | chr2:90173414 ins G | 3'Flank (INS) | VAF 22/86 reads (26%) | called by mutect2, pindel, varscan2
